Gene-level copy-number profile of tumor specimen TCGA-38-4629-01A from TCGA case TCGA-38-4629, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.7 years (25,104 days).
Specimen TCGA-38-4629-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.bf12da41-bbc7-4b51-b972-07a784eeaca6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-38-4629-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e969ea3e-c8bc-482c-b53a-f8abef296183

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 36,154; copy number 2: 15,285; copy number 3: 7,722; copy number 4: 303; copy number 5: 93; copy number 6: 27; copy number 7: 9; copy number 8: 116; copy number 9: 3; copy number 10: 31; copy number 18: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-38-4629-01): tumor purity 0.4, ploidy 2.46, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–22,824,213, 67 genes (within-gene range 0–2) (broad region; genes not listed).
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 8,305 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:137,964,020–138,107,178, 2 genes, copy number 5: HNMT, LINC01832.
- chr4:425,435–1,340,147, 38 genes, copy number 3 (within-gene range 1–3): ABCA11P, ZNF721, PIGG, TMEM271, AC116565.1, PDE6B, PDE6B-AS1, AC107464.2, ATP5ME, MYL5, SLC49A3, PCGF3, AC107464.1, AC139887.4, AC139887.2, AC139887.1, CPLX1, AC139887.3, AC139887.5, GAK, TMEM175, DGKQ, SLC26A1, IDUA, FGFRL1, AC019103.1, RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA.
- chr4:11,368,827–29,510,737, 188 genes, copy number 3 (broad region; genes not listed).
- chr4:30,718,805–190,092,279, 2,153 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr5:58,198–41,071,342, 636 genes, copy number 3–4 (broad region; genes not listed).
- chr6:101,181,257–102,070,083, 3 genes, copy number 3 (within-gene range 1–3): GRIK2, ACTG1P18, AP002528.1.
- chr7:83,663,419–85,489,293, 13 genes, copy number 3–9: RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972.
- chr7:89,882,353–92,917,187, 52 genes, copy number 5–8 (within-gene range 1–8): STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1.
- chr7:94,278,680–95,324,532, 19 genes, copy number 3 (within-gene range 1–3): AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1.
- chr7:99,876,958–105,876,604, 203 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr7:106,248,298–117,230,176, 145 genes, copy number 4–18 (within-gene range 4–23) (broad region; genes not listed).
- chr7:118,950,386–119,179,149, 2 genes, copy number 7: AC092098.1, AC079791.1.
- chr7:121,873,089–124,647,822, 41 genes, copy number 8 (within-gene range 2–8): PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1, CADPS2, AC004594.1, AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A, AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P.
- chr7:152,749,079–157,527,325, 75 genes, copy number 4–5 (broad region; genes not listed).
- chr7:157,574,336–157,740,456, 3 genes, copy number 5: MIR153-2, AC005481.1, AC006003.1.
- chr8:35,080,592–35,796,550, 4 genes, copy number 3 (within-gene range 2–3): AC099685.1, UNC5D, AC090740.1, LSM12P1.
- chr8:41,929,479–145,066,685, 1,591 genes, copy number 3 (broad region; genes not listed).
- chr9:14,475–4,348,392, 55 genes, copy number 3 (within-gene range 2–3): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1, GLIS3, AL137071.1, GLIS3-AS1, AL359095.1.
- chr11:60,615,729–61,969,490, 66 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr11:68,683,779–71,568,934, 76 genes, copy number 3–5 (broad region; genes not listed).
- chr11:120,511,746–128,183,671, 199 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr14:97,110,416–106,875,071, 540 genes, copy number 3 (broad region; genes not listed).
- chr17:26,981,694–83,095,122, 2,120 genes, copy number 3 (broad region; genes not listed).
- chr21:43,719,094–45,004,727, 81 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 34,024. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
